Somatic mutation profile of tumor specimen TCGA-27-2519-01A (aliquot TCGA-27-2519-01A-01D-1494-08) from TCGA case TCGA-27-2519, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.5 years (17,715 days).
Specimen TCGA-27-2519-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c928ffb-97dc-494a-a561-4767787c88c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-2519-10A (Blood Derived Normal), aliquot TCGA-27-2519-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef4c96cc-d305-4629-b0da-61aac5772c0b

The open-access MAF lists 45 somatic variants for this specimen: 37 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 6, Intron 2, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 103/215 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844del p.R282Gfs*63 | Frame Shift Del (DEL) | VAF 51/104 reads (49%) | catalogued as rs1131691027, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.1689G>T p.W563C | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV70032926; called by muse, mutect2
- AMPH | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs370790138; called by muse, mutect2, varscan2
- ARHGAP28 | c.726+1G>T p.X242_splice (on ENST00000383472 / NM_001366230.1; = p.X83_splice on NM_001010000.3) | Splice Site (SNP) | VAF 76/224 reads (34%) | catalogued as COSV51640523; called by muse, mutect2, varscan2
- ARHGEF5 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs368131997; called by muse, mutect2, varscan2
- ARSF | c.209A>C p.Q70P | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63840057; called by muse, varscan2
- BRSK1 | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58667791, COSV58668405; called by muse, mutect2, varscan2
- DNMBP | c.3065T>C p.V1022A | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60627970; called by muse, mutect2
- EML1 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51745669; called by muse, mutect2, varscan2
- FAM126A | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 150/689 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs757752437, COSV69471625; called by muse, mutect2, varscan2
- GABRA1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 57/229 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as rs755336024, COSV50108949, COSV99196150; called by muse, mutect2, varscan2
- GRM3 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV64468976; called by muse, mutect2, varscan2
- GRM5 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1409555487, COSV100555021, COSV59605587; called by muse, varscan2
- HTR5A | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs1031605672, COSV55283584; called by muse, mutect2
- KLKB1 | c.1213C>A p.Q405K | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs61733605, COSV52996694; called by muse, mutect2, varscan2
- MC3R | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 67/305 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV54764169; called by muse, mutect2, varscan2
- NDST4 | c.508A>T p.N170Y | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.213); catalogued as COSV52125307, COSV99079539; called by muse, mutect2, varscan2
- OR2M2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 160/542 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs150685608; called by muse, mutect2, varscan2
- OR5H6 | c.500G>C p.G167A (on ENST00000642105; = p.G151A on NM_001005479.2) | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.168); catalogued as COSV67351686; called by muse, mutect2, varscan2
- PHKA1 | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0.416); catalogued as COSV59807526; called by muse, mutect2, varscan2
- PKHD1 | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs370436973; called by muse, mutect2, varscan2
- PSD2 | c.1793C>G p.A598G | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV99217079; called by muse, mutect2, varscan2
- PTPN3 | c.2106+1G>A p.X702_splice | Splice Site (SNP) | VAF 18/49 reads (37%) | catalogued as rs769545167, COSV52704536, COSV52705478; called by muse, mutect2, varscan2
- REST | c.2783C>T p.T928M | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747423176, COSV58361418; called by muse, mutect2, varscan2
- SCN9A | c.5705G>A p.R1902H (on ENST00000303354; = p.R1891H on NM_002977.3) | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs180949263, COSV57611089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGCA | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.152); catalogued as rs779439298, COSV56249905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIGLEC11 | c.1126G>T p.G376C | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as COSV70222044; called by muse, mutect2
- SORCS1 | c.2588G>A p.G863D | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53851726, COSV53877752; called by muse, mutect2
- TCHH | c.5121A>T p.R1707S | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.145); catalogued as COSV64275740; called by muse, mutect2, varscan2
- TEX15 | c.5362C>T p.R1788* (on ENST00000256246; = p.R2171* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 29/99 reads (29%) | catalogued as rs760122658, COSV56347485; called by muse, mutect2, varscan2
- TM9SF4 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs1186412779, COSV54108205; called by muse, mutect2, varscan2
- TRABD2A | c.1273C>T p.R425W (on ENST00000409520 / NM_001277053.2; = p.R376W on NM_001080824.3) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs202220791, COSV52868053; called by muse, mutect2, varscan2
- TRPV6 | c.1520A>T p.Y507F | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as COSV63892296; called by muse, mutect2, varscan2
- ZHX2 | c.1504A>C p.T502P | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1271767148, COSV58714387; called by muse, mutect2, varscan2
- ZNF786 | c.1702G>A p.G568R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs747902874, COSV100302777, COSV60276819; called by muse, mutect2, varscan2
- MAP1B | c.3854del p.E1285Gfs*10 | Frame Shift Del (DEL) | VAF 38/126 reads (30%) | called by mutect2, pindel, varscan2
- ANO4 | c.1563C>T p.F521= (on ENST00000392977 / NM_001286615.2; = p.F486= on NM_178826.4) | Silent (SNP) | VAF 213/672 reads (32%) | catalogued as COSV54601431; called by muse, mutect2, varscan2
- CIB2 | c.96G>A p.S32= | Silent (SNP) | VAF 48/90 reads (53%) | catalogued as rs541843030, COSV51948960; called by muse, mutect2, varscan2
- CRYBG2 | c.4242C>T p.G1414= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as rs763397390, COSV57483657; called by muse, mutect2, varscan2
- FER1L6 | c.4845C>A p.I1615= | Silent (SNP) | VAF 51/153 reads (33%) | catalogued as COSV67547996, COSV67550110; called by muse, mutect2, varscan2
- KLK15 | c.588C>T p.G196= | Silent (SNP) | VAF 59/123 reads (48%) | catalogued as COSV56827415; called by muse, mutect2, varscan2
- RAB3C | c.177C>T p.F59= | Silent (SNP) | VAF 41/140 reads (29%) | catalogued as rs764929392, COSV51437890; called by muse, mutect2, varscan2
- FCRL2 | c.884-81T>C | Intron (SNP) | VAF 72/247 reads (29%) | catalogued as COSV100829850; called by muse, mutect2, varscan2
- NEBL | c.164+26028C>T | Intron (SNP) | VAF 75/165 reads (45%) | catalogued as COSV65798749; called by muse, mutect2, varscan2
